Somatic mutation profile of tumor specimen TCGA-CC-A7IH-01A (aliquot TCGA-CC-A7IH-01A-11D-A33K-10) from TCGA case TCGA-CC-A7IH, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 58.5 years (21,381 days).
Specimen TCGA-CC-A7IH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50293b7b-e9b7-4c2a-9db2-f26a5c99df25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A7IH-10A (Blood Derived Normal), aliquot TCGA-CC-A7IH-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5eb314c8-bfb3-41f5-aad8-e60ad27687bc

The open-access MAF lists 818 somatic variants for this specimen: 610 protein-altering or splice-affecting, 193 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 527, Silent 193, Nonsense Mutation 33, Splice Site 24, Frame Shift Del 11, RNA 7, Splice Region 6, Intron 5, In Frame Del 5, Frame Shift Ins 4, 3'Flank 1, 5'UTR 1.

Variants (750 of 818; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.124_147del p.T42_K49del | In Frame Del (DEL) | VAF 117/163 reads (72%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- FOXF1 | c.225C>A p.Y75* | Nonsense Mutation (SNP) | VAF 42/113 reads (37%) | catalogued as rs121909336, CM093481, COSV52288573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDH | c.155A>T p.H52L | Missense Mutation (SNP) | VAF 89/223 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as COSV52710599; called by muse, mutect2, varscan2
- ABCA1 | c.1109T>C p.I370T | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV66070548; called by muse, mutect2, varscan2
- ABCA12 | c.688T>A p.S230T | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.223); catalogued as COSV55975061; called by muse, mutect2, varscan2
- ABCA4 | c.500T>G p.L167R | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV64677933; called by muse, mutect2, varscan2
- ABCC5 | c.1745A>T p.D582V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.501); catalogued as COSV55596288; called by muse, mutect2, varscan2
- ACE | c.2353T>G p.W785G | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as rs763670346, COSV52012802, COSV99327228; called by muse, mutect2, varscan2
- ACP3 | c.1013A>T p.E338V | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV60488592; called by muse, mutect2, varscan2
- ACR | c.383T>C p.I128T | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53361942; called by muse, mutect2, varscan2
- ADAMTS13 | c.4135T>C p.W1379R | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1361529166, COSV52471600; called by muse, varscan2
- ADAMTS16 | c.2611A>T p.S871C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV57006709; called by muse, mutect2, varscan2
- ADAMTS19 | c.1087-2A>T p.X363_splice | Splice Site (SNP) | VAF 100/234 reads (43%) | catalogued as rs780963556, COSV50796883; called by muse, mutect2, varscan2
- ADAMTS2 | c.3094A>T p.I1032F | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.04); catalogued as COSV52392803; called by muse, mutect2, varscan2
- ADCY5 | c.1475T>A p.M492K | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as COSV59204319; called by muse, varscan2
- ADCY8 | c.1315C>T p.L439F | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53926817; called by muse, mutect2, varscan2
- ADGRA1 | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV66930229, COSV66931716; called by muse, mutect2, varscan2
- ADGRB1 | c.1216T>G p.C406G | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV60103377; called by muse, mutect2, varscan2
- ADGRD1 | c.283A>G p.S95G | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.807); catalogued as COSV55457024; called by muse, mutect2, varscan2
- ADGRD1 | c.1777T>A p.S593T | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1374922535, COSV99895872; called by muse, mutect2
- ADGRE3 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53734729; called by muse, mutect2, varscan2
- ADGRF1 | c.2444A>T p.Q815L | Missense Mutation (SNP) | VAF 115/432 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV51947702; called by muse, mutect2, varscan2
- ADGRF5 | c.3081G>T p.L1027F | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51937287; called by muse, mutect2, varscan2
- ADGRG4 | c.8844A>T p.L2948F | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54966515; called by muse, mutect2, varscan2
- ADNP2 | c.2801A>G p.H934R | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51542376; called by muse, mutect2, varscan2
- ADRA1B | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757479764, COSV60704032; called by muse, mutect2, varscan2
- AFDN | c.5126A>T p.Q1709L (on ENST00000447894 / NM_001366320.1; = p.Q1666L on NM_001291964.1) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV100653111; called by muse, mutect2, varscan2
- AFF2 | c.268A>G p.N90D | Missense Mutation (SNP) | VAF 172/382 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV60681110; called by muse, mutect2, varscan2
- AFMID | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV56961182, COSV56961624; called by muse, mutect2, varscan2
- AGAP3 | c.1957A>T p.S653C (on ENST00000622464; = p.S689C on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68246702; called by muse, mutect2, varscan2
- AGPAT5 | c.831G>A p.M277I | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV53449271; called by muse, mutect2
- ALKAL1 | c.337T>C p.C113R | Missense Mutation (SNP) | VAF 155/674 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62131274; called by muse, mutect2, varscan2
- ALOX12B | c.155A>T p.Q52L | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV59876347; called by muse, mutect2, varscan2
- ANK3 | c.11609C>A p.T3870N | Missense Mutation (SNP) | VAF 196/340 reads (58%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as COSV55080974; called by muse, mutect2, varscan2
- ANKRD50 | c.1624G>T p.D542Y | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV72386298; called by muse, mutect2, varscan2
- ANO8 | c.1121T>C p.L374P | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV50198692; called by muse, mutect2, varscan2
- APEX2 | c.1267A>T p.T423S | Missense Mutation (SNP) | VAF 60/83 reads (72%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV58193297; called by muse, mutect2, varscan2
- APOB | c.10227T>A p.S3409R | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV51951791; called by muse, mutect2, varscan2
- ARC | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV63079778; called by muse, mutect2, varscan2
- ARHGAP5 | c.487A>G p.I163V | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT tolerated (0.94); PolyPhen benign (0.014); catalogued as rs1566659416, COSV61539218; called by muse, mutect2, varscan2
- ARHGEF15 | c.505G>C p.D169H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); catalogued as COSV62726430; called by muse, mutect2, varscan2
- ARHGEF4 | c.2003T>C p.L668P | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58130108; called by muse, mutect2, varscan2
- ARHGEF5 | c.4299-2A>T p.X1433_splice | Splice Site (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99282891; called by mutect2, varscan2
- ARVCF | c.479A>G p.D160G | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); catalogued as rs914740422, COSV54270058; called by muse, mutect2, varscan2
- ASIC4 | c.598G>T p.G200W | Missense Mutation (SNP) | VAF 105/272 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61733436; called by muse, mutect2, varscan2
- ASTN1 | c.1640G>A p.S547N | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV56084633; called by muse, mutect2, varscan2
- ATP2C2 | c.920-2A>T p.X307_splice | Splice Site (SNP) | VAF 58/153 reads (38%) | catalogued as rs1033643441, COSV52301235; called by muse, mutect2, varscan2
- ATP6V1F | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 28/63 reads (44%) | catalogued as COSV50800276; called by muse, mutect2, varscan2
- AVPR1B | c.1030C>A p.H344N | Missense Mutation (SNP) | VAF 68/243 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV65638620; called by muse, mutect2, varscan2
- B4GALNT3 | c.2419G>T p.D807Y | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781238076, COSV56757948; called by muse, mutect2, varscan2
- BANK1 | c.762A>T p.L254F | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV59849742; called by muse, mutect2, varscan2
- BCAT2 | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60274141; called by muse, mutect2, varscan2
- BDKRB2 | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV60017005; called by muse, varscan2
- BICD1 | c.233C>G p.S78C | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV55688090; called by muse, mutect2, varscan2
- BICD1 | c.2264A>G p.Y755C | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55688101; called by muse, mutect2, varscan2
- BICD2 | c.2360A>T p.Q787L | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63550881; called by muse, mutect2, varscan2
- BRINP2 | c.976T>C p.S326P | Missense Mutation (SNP) | VAF 68/678 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV64180164; called by muse, mutect2
- BRIX1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 128/358 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59132059; called by muse, mutect2, varscan2
- BRPF3 | c.1061A>C p.Q354P | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60209739; called by muse, mutect2, varscan2
- BTBD11 | c.1900-2A>C p.X634_splice (on ENST00000280758 / NM_001018072.2; = p.X171_splice on NM_001017523.2) | Splice Site (SNP) | VAF 42/107 reads (39%) | catalogued as COSV55037203; called by muse, mutect2, varscan2
- C5orf22 | c.225T>C p.F75= | Splice Region (SNP) | VAF 22/87 reads (25%) | catalogued as COSV57599949; called by muse, mutect2, varscan2
- C6orf47 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 46/239 reads (19%) | catalogued as COSV100789017, COSV63264161; called by muse, mutect2, varscan2
- CABP5 | c.366T>A p.D122E | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV53154033; called by muse, mutect2
- CACNA1D | c.1098G>A p.W366* | Nonsense Mutation (SNP) | VAF 6/126 reads (5%) | catalogued as COSV55464511; called by muse, mutect2
- CACNA1E | c.5535C>A p.H1845Q | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs866465909, COSV62420692; called by muse, mutect2, varscan2
- CACNA2D1 | c.637G>T p.G213C | Missense Mutation (SNP) | VAF 106/247 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62392130; called by muse, mutect2, varscan2
- CAMK2N1 | c.113C>G p.A38G | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66757648; called by muse, mutect2, varscan2
- CAMKMT | c.438G>A p.R146= | Splice Region (SNP) | VAF 37/85 reads (44%) | catalogued as COSV65929275; called by muse, mutect2, varscan2
- CARD11 | c.1753A>T p.S585C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV62757090; called by muse, mutect2, varscan2
- CARTPT | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs751106151, COSV57115836; called by muse, mutect2, varscan2
- CAVIN4 | c.889A>G p.I297V | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.96); PolyPhen benign (0.015); catalogued as COSV56868345; called by muse, mutect2, varscan2
- CC2D1A | c.1021G>T p.V341L | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV58786151; called by muse, mutect2, varscan2
- CCDC105 | c.470A>G p.Q157R | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.861); catalogued as COSV52965638; called by muse, mutect2, varscan2
- CCDC136 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 76/202 reads (38%) | catalogued as COSV52804201; called by muse, varscan2
- CCDC136 | c.1973T>G p.L658W | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52804768; called by muse, mutect2, varscan2
- CCDC178 | c.2399T>A p.L800Q (on ENST00000383096 / NM_001105528.3; = p.L762Q on NM_198995.3) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55796803; called by muse, mutect2, varscan2
- CCDC189 | c.323T>A p.L108Q | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV60313774; called by muse, mutect2, varscan2
- CCDC80 | c.575A>G p.Q192R | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV52819878; called by muse, mutect2, varscan2
- CCKBR | c.812-2A>G p.X271_splice | Splice Site (SNP) | VAF 24/40 reads (60%) | catalogued as COSV58105508; called by muse, mutect2, varscan2
- CCL25 | c.17T>A p.L6Q | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53665095; called by muse, mutect2, varscan2
- CCNF | c.1219-2A>T p.X407_splice | Splice Site (SNP) | VAF 24/59 reads (41%) | catalogued as COSV53543152; called by muse, mutect2, varscan2
- CCSER1 | c.419A>G p.E140G | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV61467575; called by muse, mutect2, varscan2
- CCT4 | c.180G>C p.M60I | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV66702068; called by muse, mutect2, varscan2
- CD200R1L | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as COSV68004925; called by muse, mutect2, varscan2
- CD22 | c.358A>T p.R120W | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50068016; called by muse, mutect2, varscan2
- CD69 | c.260A>G p.E87G | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs746297540, COSV57303776; called by muse, mutect2, varscan2
- CDCA7 | c.658-2A>C p.X220_splice (on ENST00000347703 / NM_145810.3; = p.X299_splice on NM_031942.5) | Splice Site (SNP) | VAF 32/61 reads (52%) | catalogued as COSV60721817; called by muse, mutect2, varscan2
- CDK2AP2 | c.221A>G p.Y74C | Missense Mutation (SNP) | VAF 97/206 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56874542; called by muse, mutect2, varscan2
- CDK9 | c.920A>T p.D307V | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV64724205; called by muse, mutect2, varscan2
- CELF2 | c.191G>A p.G64E (on ENST00000416382 / NM_001025077.3; = p.G71E on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/106 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59982537; called by muse, mutect2, varscan2
- CELSR2 | c.3623G>C p.R1208P | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV54768188, COSV54779248; called by muse, mutect2, varscan2
- CEP192 | c.7048-2A>T p.X2350_splice | Splice Site (SNP) | VAF 30/67 reads (45%) | catalogued as COSV100381325, COSV58070521; called by muse, mutect2, varscan2
- CFAP251 | c.2852A>G p.K951R | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV56615848; called by muse, mutect2
- CFAP61 | c.2915T>C p.I972T | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as rs1569246723, COSV55647206; called by muse, mutect2, varscan2
- CFAP94 | c.1480C>T p.Q494* (on ENST00000320267 / NM_001352064.2; = p.Q500* on NM_018272.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 43/108 reads (40%) | catalogued as COSV57236701; called by muse, mutect2, varscan2
- CHD8 | c.6106C>T p.P2036S (on ENST00000646647 / NM_001170629.2; = p.P1757S on NM_020920.4) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.067); catalogued as rs1192042781, COSV63036454, COSV63037465; called by muse, varscan2
- CHD9 | c.5860A>T p.N1954Y | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV54616318; called by muse, mutect2, varscan2
- CHRM5 | c.302T>G p.L101R | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67248664; called by muse, mutect2, varscan2
- CIC | c.2189C>G p.S730W | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); catalogued as COSV50663567; called by muse, mutect2, varscan2
- CLCN1 | c.2402A>T p.E801V | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV58374374; called by muse, mutect2, varscan2
- CLEC14A | c.818G>A p.C273Y | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1377042221, COSV60564230; called by muse, mutect2, varscan2
- CLEC1B | c.445A>T p.I149F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV53726629; called by muse, mutect2
- CLN6 | c.373A>T p.S125C | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV51118188; called by muse, mutect2, varscan2
- CNGA4 | c.1139A>T p.D380V | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs892620380, COSV66007064; called by muse, mutect2, varscan2
- CNTNAP4 | c.1681G>A p.G561S | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs150806968, COSV100271916, COSV56695578; called by muse, mutect2, varscan2
- COG1 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs149528257; called by muse, mutect2, varscan2
- COL22A1 | c.2714A>C p.Q905P | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.308); catalogued as COSV57360097; called by muse, mutect2, varscan2
- COL4A2 | c.4475T>A p.L1492Q | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64634033; called by muse, mutect2, varscan2
- COL6A6 | c.2876T>G p.M959R | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV62037278; called by muse, mutect2, varscan2
- CPEB1 | c.724A>T p.S242C (on ENST00000617958; = p.S182C on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55621428; called by muse, mutect2, varscan2
- CRB2 | c.1790A>T p.E597V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as COSV63505511; called by muse, mutect2, varscan2
- CSHL1 | c.509T>A p.L170H (on ENST00000309894 / NM_022581.3; = p.L76H on NM_001318.4) | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV51990000; called by muse, mutect2, varscan2
- CSMD1 | c.455T>A p.L152Q | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.522); catalogued as COSV68258116; called by muse, mutect2, varscan2
- CSMD2 | c.3340T>C p.F1114L | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs749364603, COSV53922691, COSV53961191; called by muse, mutect2, varscan2
- CSMD3 | c.7422T>A p.Y2474* (on ENST00000297405 / NM_001363185.1; = p.Y2370* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 79/334 reads (24%) | catalogued as COSV52315486; called by muse, mutect2, varscan2
- CSMD3 | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 140/302 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.404); catalogued as COSV52315510; called by muse, mutect2, varscan2
- CTAG2 | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 83/167 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55996799; called by muse, mutect2, varscan2
- CTAGE15 | c.885A>T p.L295F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as rs1427172281; called by mutect2, varscan2
- CTTNBP2 | c.2807G>T p.G936V | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.282); catalogued as COSV50473398; called by muse, mutect2, varscan2
- CUL9 | c.1505T>C p.L502P | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52734549; called by muse, mutect2, varscan2
- DACH2 | c.703A>T p.N235Y | Missense Mutation (SNP) | VAF 133/278 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100913696, COSV64185566; called by muse, mutect2, varscan2
- DAZAP1 | c.1195G>C p.V399L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV51831845, COSV51836283; called by muse, mutect2, varscan2
- DBN1 | c.998T>C p.I333T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.047); catalogued as COSV52793076; called by muse, mutect2
- DBNL | c.442C>A p.R148S | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV68882501; called by muse, mutect2, varscan2
- DCAF10 | c.1313G>T p.C438F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV54288137, COSV54291804; called by muse, mutect2, varscan2
- DCAF12L2 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63584135; called by muse, mutect2, varscan2
- DCC | c.2767A>T p.T923S | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV59134591; called by muse, mutect2, varscan2
- DDX10 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV59439910; called by muse, mutect2, varscan2
- DENND3 | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52806797; called by muse, mutect2, varscan2
- DEPDC1B | c.1235G>T p.R412I | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV54013129; called by muse, mutect2, varscan2
- DICER1 | c.5096-1G>T p.X1699_splice | Splice Site (SNP) | VAF 17/46 reads (37%) | catalogued as COSV58628042; called by muse, mutect2, varscan2
- DLGAP5 | c.1584C>G p.I528M | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV55965336; called by muse, mutect2, varscan2
- DMBT1 | c.940C>A p.P314T | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.922); catalogued as rs947126229, COSV57561543; called by muse, varscan2
- DNAH2 | c.1949T>A p.L650Q | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66727113; called by muse, mutect2, varscan2
- DNAH7 | c.7130A>T p.H2377L | Missense Mutation (SNP) | VAF 63/134 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV56785505; called by muse, varscan2
- DNAH7 | c.218A>T p.E73V | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); catalogued as COSV56785522; called by muse, mutect2, varscan2
- DNAH9 | c.8195A>G p.Q2732R | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0.014); catalogued as COSV52376303, COSV99308402; called by muse, mutect2, varscan2
- DPH6 | c.154A>T p.T52S | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.598); catalogued as COSV56619565; called by muse, mutect2, varscan2
- DPP10 | c.1951-1G>T p.X651_splice | Splice Site (SNP) | VAF 44/120 reads (37%) | catalogued as COSV59669368; called by muse, varscan2
- DPP4 | c.423G>T p.Q141H | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.394); catalogued as COSV62109748; called by muse, mutect2, varscan2
- DSCAML1 | c.1871T>A p.V624E (on ENST00000321322; = p.V564E on NM_020693.4) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58402488; called by muse, mutect2, varscan2
- DSE | c.2042A>T p.Q681L | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV59067308; called by muse, mutect2, varscan2
- DSP | c.249G>T p.M83I | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV65791559, COSV65795914; called by muse, varscan2
- DSP | c.4596G>T p.E1532D | Missense Mutation (SNP) | VAF 70/256 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.918); catalogued as COSV65795922; called by muse, mutect2, varscan2
- DSP | c.5233A>G p.K1745E | Missense Mutation (SNP) | VAF 69/314 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV65795928; called by muse, mutect2, varscan2
- DST | c.21877C>T p.R7293* (on ENST00000361203 / NM_001374722.1; = p.R4966* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 28/157 reads (18%) | catalogued as COSV55039324; called by muse, mutect2, varscan2
- DST | c.3018G>T p.Q1006H (on ENST00000361203 / NM_001374722.1; = p.Q680H on NM_001723.6) | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as COSV55039344; called by muse, mutect2, varscan2
- DYNC2H1 | c.1122T>G p.N374K | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV62106536; called by muse, mutect2, varscan2
- DYNC2H1 | c.3729A>T p.K1243N | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as COSV62106543; called by muse, mutect2, varscan2
- DZIP1L | c.1706C>A p.P569Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.726); catalogued as COSV59523424; called by muse, varscan2
- ECSIT | c.805A>G p.S269G | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV52940915; called by muse, mutect2, varscan2
- EDN1 | c.11T>G p.L4W | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV65081348; called by muse, varscan2
- EEF1AKNMT | c.473G>T p.C158F (on ENST00000361735 / NM_015935.5; = p.C72F on NM_014955.3) | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62283813; called by muse, mutect2, varscan2
- EEF1E1 | c.179T>C p.L60S | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65676091; called by muse, mutect2, varscan2
- EFNB2 | c.963G>A p.M321I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.145); catalogued as COSV55362992, COSV55367456; called by muse, mutect2, varscan2
- EGF | c.2392A>G p.N798D | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV54484613; called by muse, mutect2, varscan2
- ELF5 | c.283A>T p.S95C (on ENST00000312319 / NM_198381.2; = p.S85C on NM_001422.4) | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV56630451; called by muse, mutect2, varscan2
- EMILIN1 | c.95A>G p.Y32C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66695473; called by muse, mutect2, varscan2
- ENPP2 | c.731T>A p.L244Q | Missense Mutation (SNP) | VAF 88/184 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50038668; called by muse, mutect2, varscan2
- ENTHD1 | c.379G>T p.V127F | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV57325008; called by muse, mutect2, varscan2
- EPB41L3 | c.2645C>A p.A882E | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV59452661; called by muse, mutect2, varscan2
- EPHA2 | c.2036A>T p.E679V | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64454705; called by muse, mutect2, varscan2
- EPHA5 | c.1082C>G p.P361R | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56673278, COSV56683185; called by muse, mutect2, varscan2
- EPHA5 | c.890A>T p.E297V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV56673294; called by muse, mutect2, varscan2
- EPHA5 | c.334T>A p.W112R | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56673308; called by muse, mutect2, varscan2
- EPHA6 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 188/464 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745907900, COSV67593459; called by muse, varscan2
- EPRS1 | c.3129A>G p.I1043M | Missense Mutation (SNP) | VAF 91/444 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV65101530; called by muse, mutect2, varscan2
- ERCC4 | c.469A>T p.K157* | Nonsense Mutation (SNP) | VAF 30/74 reads (41%) | catalogued as COSV61313941; called by muse, mutect2, varscan2
- EVC2 | c.3110C>T p.A1037V | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV60402390; called by muse, mutect2, varscan2
- EVC2 | c.1284G>T p.M428I | Missense Mutation (SNP) | VAF 73/133 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV60402403; called by muse, mutect2, varscan2
- EXOSC10 | c.1303A>T p.S435C | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as COSV58668072; called by muse, mutect2, varscan2
- FAM13B | c.1988A>G p.K663R | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50373992; called by muse, mutect2, varscan2
- FAM13C | c.1243A>C p.K415Q | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as COSV53255858; called by muse, varscan2
- FAM163A | c.372T>G p.F124L | Missense Mutation (SNP) | VAF 38/350 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV59205756; called by muse, mutect2
- FAM71B | c.935C>A p.A312E | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs200982218, COSV57231192, COSV57231592; called by muse, mutect2, varscan2
- FAM71F2 | c.778A>G p.K260E | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV66352446; called by muse, mutect2, varscan2
- FAM83B | c.1121A>T p.Q374L | Missense Mutation (SNP) | VAF 90/386 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV60926684; called by muse, mutect2, varscan2
- FAM98B | c.930A>C p.E310D | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV67023700; called by muse, mutect2, varscan2
- FARP2 | c.1381C>T p.L461F | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV50881500; called by muse, mutect2, varscan2
- FASTK | c.1040G>A p.G347D | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1205078858, COSV52542256; called by muse, mutect2, varscan2
- FAT2 | c.4540C>T p.L1514F | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.042); catalogued as rs556459301, COSV55813000; called by muse, mutect2, varscan2
- FAT3 | c.4142T>C p.V1381A | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV53172663; called by muse, mutect2, varscan2
- FBLN1 | c.1814C>T p.T605I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV59942479; called by muse, mutect2, varscan2
- FBN1 | c.5603C>A p.T1868K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as COSV104413953, COSV57330170; called by muse, mutect2, varscan2
- FGFBP1 | c.140A>T p.Q47L | Missense Mutation (SNP) | VAF 123/209 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV52587286; called by muse, mutect2, varscan2
- FLG | c.6800A>T p.H2267L | Missense Mutation (SNP) | VAF 68/350 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV64248979; called by muse, varscan2
- FLG2 | c.2149T>C p.S717P | Missense Mutation (SNP) | VAF 54/270 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.249); catalogued as rs774741236, COSV66173198; called by muse, varscan2
- FLG2 | c.439T>A p.S147T | Missense Mutation (SNP) | VAF 259/368 reads (70%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.868); catalogued as COSV66173206; called by muse, mutect2, varscan2
- FMNL1 | c.584C>A p.S195Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.123); catalogued as COSV58959176; called by muse, mutect2, varscan2
- FMOD | c.806A>G p.K269R | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV61610596; called by muse, mutect2, varscan2
- FNDC1 | c.3361G>T p.A1121S | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.364); catalogued as COSV51947704; called by muse, mutect2
- FNTB | c.1223T>G p.V408G | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV55764330; called by muse, mutect2, varscan2
- FOXB2 | c.877T>A p.S293T | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.931); catalogued as COSV65024090; called by muse, mutect2, varscan2
- FOXD4L3 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.272); catalogued as rs1554670695, COSV100731014; called by muse, mutect2, varscan2
- FOXN2 | c.1177A>G p.I393V | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.145); catalogued as COSV61319851; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1648A>T p.K550* | Nonsense Mutation (SNP) | VAF 107/317 reads (34%) | catalogued as COSV58565719; called by muse, mutect2, varscan2
- FREM1 | c.353T>G p.I118R | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs375644504, COSV101085755; called by muse, mutect2, varscan2
- FRMD5 | c.331T>A p.Y111N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68725388; called by muse, mutect2, varscan2
- FRS3 | c.565-2A>T p.X189_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV52486926; called by muse, mutect2, varscan2
- FURIN | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 51/113 reads (45%) | catalogued as COSV51579666; called by muse, mutect2, varscan2
- FZD1 | c.1369A>G p.I457V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1326242104, COSV55313454; called by muse, mutect2, varscan2
- FZD10 | c.515A>C p.Q172P | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV57475845; called by muse, mutect2, varscan2
- GABBR1 | c.767C>A p.A256D | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs907203508, COSV63544508; called by muse, mutect2, varscan2
- GABBR1 | c.101A>T p.H34L | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.096); catalogued as COSV63544509; called by muse, mutect2, varscan2
- GABRA5 | c.59T>A p.I20N | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV59485767; called by muse, mutect2, varscan2
- GATM | c.188A>C p.D63A | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV67541143; called by muse, mutect2, varscan2
- GBGT1 | c.376C>G p.Q126E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.182); catalogued as COSV64410603; called by muse, mutect2, varscan2
- GBP6 | c.1295A>G p.H432R | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV65012590; called by muse, mutect2, varscan2
- GDPD1 | c.931A>T p.N311Y | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV52384781; called by muse, mutect2, varscan2
- GH2 | c.622T>C p.C208R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766528940, COSV60427851; called by muse, mutect2, varscan2
- GJD2 | c.515A>G p.K172R | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); catalogued as rs763718869, COSV51749959; called by muse, varscan2
- GLI4 | c.49G>T p.V17F | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs1197379102, COSV60682806; called by muse, mutect2, varscan2
- GLP1R | c.563T>A p.I188N | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64716403; called by muse, mutect2, varscan2
- GPATCH2 | c.1019-1G>T p.X340_splice | Splice Site (SNP) | VAF 34/118 reads (29%) | catalogued as COSV65128566; called by muse, mutect2, varscan2
- GPC4 | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 89/192 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0.03); catalogued as rs757840938, COSV63699754; called by muse, mutect2, varscan2
- GPSM1 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1554769464, COSV61305689; called by muse, mutect2, varscan2
- GRIA2 | c.182A>G p.H61R | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.976); catalogued as COSV52405733; called by muse, varscan2
- GRIK3 | c.1326+2T>C p.X442_splice | Splice Site (SNP) | VAF 15/43 reads (35%) | catalogued as COSV66146635; called by muse, mutect2, varscan2
- GRIP2 | c.1184T>C p.L395P (on ENST00000619221; = p.L298P on NM_001080423.4) | Missense Mutation (SNP) | VAF 53/73 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56124892; called by muse, mutect2, varscan2
- GRK2 | c.442-2A>T p.X148_splice | Splice Site (SNP) | VAF 76/163 reads (47%) | catalogued as COSV57953974; called by muse, mutect2, varscan2
- GRK7 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53825354; called by muse, mutect2, varscan2
- GRM3 | c.1264A>G p.M422V | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as COSV64479502; called by muse, mutect2, varscan2
- GRM4 | c.2429A>T p.Q810L | Missense Mutation (SNP) | VAF 62/350 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV65219532; called by muse, mutect2, varscan2
- GRM5 | c.1231C>A p.L411I | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59629023; called by muse, mutect2, varscan2
- GRXCR2 | c.694T>A p.C232S | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1561673901, COSV65061878; called by muse, mutect2
- GSDMC | c.413T>C p.L138S | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV52699230; called by muse, mutect2, varscan2
- GTF3C1 | c.6162G>T p.K2054N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV62244871; called by muse, mutect2, varscan2
- H3C4 | c.215T>G p.V72G | Missense Mutation (SNP) | VAF 63/329 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); catalogued as COSV61912406; called by muse, mutect2, varscan2
- HACD4 | c.602T>C p.M201T | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV72217714; called by muse, mutect2, varscan2
- HAS1 | c.1015G>T p.D339Y | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55789672; called by muse, mutect2, varscan2
- HDAC9 | c.1574A>G p.N525S | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV67784986; called by muse, mutect2, varscan2
- HECTD1 | c.1276C>T p.Q426* | Nonsense Mutation (SNP) | VAF 119/299 reads (40%) | catalogued as COSV67949093; called by muse, mutect2, varscan2
- HECTD4 | c.3698A>T p.K1233I | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61181556; called by muse, mutect2, varscan2
- HECW1 | c.1727del p.G576Afs*236 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | catalogued as COSV67820911; called by mutect2, varscan2
- HECW2 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.048); catalogued as COSV53673991; called by muse, mutect2, varscan2
- HELZ2 | c.212A>T p.D71V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV64410476; called by muse, mutect2, varscan2
- HIPK3 | c.1317G>T p.M439I | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV57565594; called by muse, mutect2, varscan2
- HMMR | c.850A>G p.K284E | Missense Mutation (SNP) | VAF 130/294 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as COSV62375458; called by muse, varscan2
- HRH4 | c.902T>C p.L301S | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV56929684; called by muse, mutect2, varscan2
- HRNR | c.7916C>A p.S2639Y | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.907); catalogued as COSV100913582; called by muse, mutect2, varscan2
- HSPA13 | c.1139A>C p.K380T | Missense Mutation (SNP) | VAF 69/143 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53466466; called by muse, mutect2, varscan2
- HSPA1L | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 131/525 reads (25%) | catalogued as COSV65149487; called by muse, varscan2
- ICAM5 | c.1673G>T p.R558L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as rs147604357, COSV55746016, COSV55746091; called by muse, mutect2, varscan2
- IFFO1 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.948); catalogued as COSV60739339; called by muse, varscan2
- IFI35 | c.857G>T p.G286V (on ENST00000415816 / NM_001330230.2; = p.G288V on NM_005533.5) | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV55896963; called by muse, mutect2, varscan2
- IFNAR1 | c.463A>T p.M155L | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as rs753923384, COSV54254345; called by muse, mutect2
- IFT81 | c.62A>G p.Y21C | Missense Mutation (SNP) | VAF 79/234 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1248996456, COSV54366537; called by muse, mutect2, varscan2
- IHO1 | c.916T>C p.W306R | Missense Mutation (SNP) | VAF 54/62 reads (87%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1405932947, COSV56510906; called by muse, mutect2, varscan2
- IKBKB | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 59/90 reads (66%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV60599838; called by muse, mutect2, varscan2
- IL17C | c.71T>A p.L24H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.431); catalogued as COSV54919364; called by muse, mutect2, varscan2
- IL18RAP | c.435A>T p.L145F | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51829274; called by muse, mutect2, varscan2
- IMPA2 | c.285C>A p.S95R | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV52321467; called by muse, mutect2, varscan2
- IMPG1 | c.451C>A p.L151M | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV64061770; called by muse, mutect2, varscan2
- INPP4B | c.2718G>T p.M906I | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.269); catalogued as COSV53744940; called by muse, mutect2, varscan2
- INSRR | c.1667A>T p.Q556L | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as COSV63877226; called by muse, mutect2, varscan2
- IRAK3 | c.1068T>A p.D356E | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54165819; called by muse, mutect2, varscan2
- IRGC | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.122); catalogued as COSV54986242; called by muse, mutect2, varscan2
- IRX1 | c.1310C>A p.P437Q | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV57362364; called by muse, mutect2, varscan2
- ISLR2 | c.1901C>G p.P634R | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as rs1567164849, COSV62303739; called by muse, mutect2, varscan2
- ITGA11 | c.2638G>T p.E880* | Nonsense Mutation (SNP) | VAF 38/100 reads (38%) | catalogued as COSV59881900; called by muse, mutect2
- ITPR3 | c.3689A>G p.Q1230R | Missense Mutation (SNP) | VAF 80/273 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.58); catalogued as COSV65414788; called by muse, mutect2, varscan2
- IVL | c.947T>A p.L316Q | Missense Mutation (SNP) | VAF 130/291 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV64217085; called by muse, varscan2
- KBTBD12 | c.892A>T p.S298C | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as COSV59681961; called by muse, mutect2, varscan2
- KBTBD8 | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 87/251 reads (35%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.954); catalogued as COSV55131433; called by muse, mutect2, varscan2
- KCNA2 | c.431A>T p.E144V | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.716); catalogued as COSV60371469; called by muse, mutect2, varscan2
- KCNA3 | c.1225G>T p.V409F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63902578; called by muse, mutect2, varscan2
- KCNAB1 | c.179T>A p.L60Q | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.125); catalogued as COSV67490216; called by muse, mutect2, varscan2
- KCNH1 | c.563T>A p.L188Q | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV55085402, COSV55103196; called by muse, mutect2, varscan2
- KCNK18 | c.1024A>G p.I342V | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.141); catalogued as rs773008291, COSV57973248; called by muse, mutect2, varscan2
- KCNQ3 | c.2545G>T p.G849C | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV66468748, COSV66481582; called by muse, varscan2
- KDR | c.1368C>G p.I456M | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55775834; called by muse, mutect2, varscan2
- KIAA1217 | c.4879A>T p.R1627W | Missense Mutation (SNP) | VAF 64/119 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV56823627; called by muse, mutect2
- KIAA1586 | c.647A>G p.H216R | Missense Mutation (SNP) | VAF 59/253 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs755606740, COSV66057436; called by muse, mutect2, varscan2
- KIF18A | c.19G>T p.D7Y | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV54182844, COSV54187508; called by muse, varscan2
- KIF24 | c.1454G>T p.C485F | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV61458058; called by muse, mutect2, varscan2
- KIF26A | c.2120C>A p.A707D | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV59470457; called by muse, mutect2, varscan2
- KIF26B | c.1669A>T p.I557F | Missense Mutation (SNP) | VAF 101/480 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV63651980; called by muse, mutect2, varscan2
- KIT | c.590C>A p.S197* | Nonsense Mutation (SNP) | VAF 33/72 reads (46%) | catalogued as COSV55409209, COSV55420906; called by muse, mutect2, varscan2
- KITLG | c.371A>G p.K124R | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs1263690103, COSV57203992; called by muse, mutect2, varscan2
- KLC2 | c.460-2A>T p.X154_splice | Splice Site (SNP) | VAF 41/102 reads (40%) | catalogued as COSV57584298; called by muse, mutect2, varscan2
- KMT2D | c.9116A>G p.D3039G | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56485328; called by muse, mutect2, varscan2
- KRT23 | c.866A>G p.E289G | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52928679; called by muse, mutect2, varscan2
- KRT34 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs781546162, COSV67450661; called by muse, mutect2, varscan2
- KRT5 | c.178T>A p.Y60N | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV52863394; called by muse, mutect2, varscan2
- KRTAP5-3 | c.118T>A p.C40S | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.279); catalogued as COSV68791228; called by muse, mutect2, varscan2
- KRTAP5-6 | c.54_74del p.G20_S26del | In Frame Del (DEL) | VAF 43/123 reads (35%) | catalogued as rs747687981; called by mutect2, varscan2
- LAMB3 | c.3249A>T p.Q1083H | Missense Mutation (SNP) | VAF 47/268 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV50526509; called by muse, mutect2, varscan2
- LAMB4 | c.2575A>T p.S859C | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV52730898; called by muse, mutect2, varscan2
- LAPTM5 | c.90C>G p.I30M | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV53854492; called by muse, mutect2, varscan2
- LDB3 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV53949451; called by muse, mutect2, varscan2
- LRRC46 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51621306; called by muse, mutect2
- LRRC7 | c.2917del p.L973* (on ENST00000651989 / NM_001370785.2; = p.L940* on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 104/236 reads (44%) | catalogued as COSV50466223; called by mutect2, varscan2
- LRRIQ1 | c.3917G>T p.S1306I | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV67838433; called by muse, mutect2, varscan2
- LRRIQ3 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 133/341 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV63049834; called by muse, mutect2, varscan2
- LRRK1 | c.417G>T p.L139F | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs775524685, COSV52613074, COSV52625765; called by muse, mutect2, varscan2
- LRTM1 | c.479A>T p.Q160L | Missense Mutation (SNP) | VAF 116/132 reads (88%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV55581062; called by muse, mutect2, varscan2
- LY9 | c.986T>C p.I329T | Missense Mutation (SNP) | VAF 155/249 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as rs1009660085, COSV54437797; called by muse, mutect2, varscan2
- MAB21L1 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV59822073; called by muse, mutect2, varscan2
- MAB21L2 | c.383T>C p.I128T | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV58263566; called by muse, mutect2, varscan2
- MAEL | c.820A>C p.M274L | Missense Mutation (SNP) | VAF 20/405 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV63112652; called by muse, mutect2
- MAGEB6B | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs749257518; called by muse, mutect2, varscan2
- MALT1 | c.2273A>G p.H758R | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.01); catalogued as COSV61936535; called by muse, mutect2, varscan2
- MAP3K21 | c.2332A>T p.T778S | Missense Mutation (SNP) | VAF 59/279 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64042585; called by muse, mutect2, varscan2
- MARS2 | c.743A>T p.E248V | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV56572418; called by muse, varscan2
- MC5R | c.430A>C p.I144L | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61255711; called by muse, mutect2, varscan2
- MCF2 | c.710T>A p.L237Q | Missense Mutation (SNP) | VAF 320/727 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100644299, COSV58494905; called by muse, varscan2
- MEFV | c.137A>T p.Q46L | Missense Mutation (SNP) | VAF 64/132 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV54827456; called by muse, mutect2, varscan2
- MEN1 | c.730A>G p.M244V | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV53648404; called by muse, mutect2, varscan2
- MEP1B | c.1540A>C p.N514H | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.393); catalogued as COSV52499932; called by muse, mutect2, varscan2
- MGAM | c.2969C>T p.S990F | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); catalogued as rs1439293104, COSV101527406, COSV72075825; called by muse, mutect2, varscan2
- MGAM | c.4352A>G p.E1451G | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.108); catalogued as COSV72075829; called by muse, mutect2, varscan2
- MICALL1 | c.1083-2A>T p.X361_splice | Splice Site (SNP) | VAF 41/97 reads (42%) | catalogued as rs774299265, COSV53243339; called by muse, mutect2, varscan2
- MLX | c.555G>T p.Q185H | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV53818906; called by muse, mutect2, varscan2
- MPIG6B | c.157T>C p.C53R | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65390338; called by muse, mutect2, varscan2
- MROH5 | c.3853A>G p.T1285A | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.169); catalogued as rs1280407217, COSV61472816; called by muse, mutect2, varscan2
- MRPS27 | c.923A>T p.Q308L | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV54653554; called by muse, mutect2, varscan2
- MRTFB | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV57961605; called by muse, mutect2, varscan2
- MTCL1 | c.5159C>A p.P1720H (on ENST00000306329 / NM_001378206.1; = p.P1401H on NM_015210.4) | Missense Mutation (SNP) | VAF 88/220 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV60411670; called by muse, varscan2
- MTMR11 | c.1465-2A>G p.X489_splice (on ENST00000439741 / NM_001145862.2; = p.X417_splice on NM_181873.3) | Splice Site (SNP) | VAF 11/74 reads (15%) | catalogued as COSV54966875; called by muse, mutect2, varscan2
- MTUS2 | c.3508T>C p.L1170= (on ENST00000612955 / NM_001366650.1; = p.L149= on NM_015233.6) | Splice Region (SNP) | VAF 33/92 reads (36%) | catalogued as COSV60158653; called by muse, mutect2, varscan2
- MUC16 | c.33514A>G p.I11172V | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.009); catalogued as COSV67492811; called by muse, mutect2, varscan2
- MUC6 | c.504C>G p.Y168* | Nonsense Mutation (SNP) | VAF 47/117 reads (40%) | catalogued as COSV70149926; called by muse, mutect2, varscan2
- MX2 | c.842A>T p.E281V | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779670834, COSV58099543; called by muse, varscan2
- MYH4 | c.4846C>A p.L1616M | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV55125992; called by muse, mutect2, varscan2
- MYH7 | c.524T>G p.L175R | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62517561; called by muse, mutect2, varscan2
- MYO15A | c.9010G>T p.A3004S | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1293095516, COSV52765900; called by muse, varscan2
- MYO3A | c.1544G>T p.R515L | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200209381, COSV56330720, COSV56338173; called by muse, mutect2, varscan2
- MYT1 | c.1595C>A p.P532H | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV60513313; called by muse, mutect2, varscan2
- MYT1L | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | catalogued as COSV67732314; called by muse, mutect2, varscan2
- NABP2 | c.319A>G p.N107D | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV57193626; called by muse, mutect2, varscan2
- NACA2 | c.574A>T p.R192* | Nonsense Mutation (SNP) | VAF 44/111 reads (40%) | catalogued as COSV71713199; called by muse, mutect2
- NANOS3 | c.346T>A p.Y116N (on ENST00000397555; = p.Y135N on NM_001098622.2) | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59249934; called by muse, mutect2, varscan2
- NANP | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV59160624; called by muse, mutect2, varscan2
- NAV3 | c.3476C>G p.T1159S | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.03); catalogued as COSV57111348; called by muse, mutect2, varscan2
- NBR1 | c.1936A>G p.T646A | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.625); catalogued as COSV57835523; called by muse, mutect2
- NCOA6 | c.5956A>T p.R1986* | Nonsense Mutation (SNP) | VAF 50/114 reads (44%) | catalogued as COSV62867807; called by muse, mutect2, varscan2
- NEB | c.4804T>A p.Y1602N | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV51459385, COSV99424845; called by muse, mutect2, varscan2
- NEBL | c.1617C>A p.S539R | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as COSV65805723; called by muse, mutect2, varscan2
- NEBL | c.258+1G>T p.X86_splice | Splice Site (SNP) | VAF 164/287 reads (57%) | catalogued as COSV65800193; called by muse, mutect2, varscan2
- NEO1 | c.2881G>C p.V961L | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV56078131; called by muse, mutect2, varscan2
- NLGN4X | c.450C>A p.N150K | Missense Mutation (SNP) | VAF 41/49 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52035929; called by muse, mutect2, varscan2
- NLRP10 | c.1222A>T p.R408W | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV60782630; called by muse, mutect2, varscan2
- NME1 | c.386A>T p.E129V | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50148339; called by muse, mutect2, varscan2
- NOS1 | c.1786A>G p.T596A | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV100501100, COSV57621664; called by muse, mutect2, varscan2
- NOSTRIN | c.130A>C p.S44R | Missense Mutation (SNP) | VAF 210/565 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as COSV58324142; called by muse, mutect2, varscan2
- NPAP1 | c.210G>T p.R70S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV61511006; called by muse, mutect2, varscan2
- NPAS3 | c.2754C>G p.Y918* (on ENST00000356141 / NM_001164749.2; = p.Y886* on NM_022123.3) | Nonsense Mutation (SNP) | VAF 33/95 reads (35%) | catalogued as COSV60861703; called by muse, mutect2, varscan2
- NRXN1 | c.4295C>A p.S1432* | Nonsense Mutation (SNP) | VAF 51/117 reads (44%) | catalogued as COSV60498659; called by muse, mutect2, varscan2
- NSMCE1 | c.59A>G p.Q20R | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63864846; called by muse, mutect2, varscan2
- NTNG2 | c.1138A>G p.T380A | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV100647526; called by muse, mutect2
- NTRK3 | c.2101T>A p.S701T | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62314891; called by muse, mutect2, varscan2
- NUDC | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV58326412; called by muse, mutect2, varscan2
- NUP153 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV50465039; called by muse, mutect2, varscan2
- NUP210 | c.2105A>G p.N702S | Missense Mutation (SNP) | VAF 95/108 reads (88%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV54413899; called by muse, mutect2, varscan2
- NYNRIN | c.2659G>A p.A887T | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV66844977; called by muse, mutect2, varscan2
- OBSCN | c.5875G>T p.D1959Y | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as COSV52827811; called by muse, mutect2, varscan2
- OBSCN | c.21467A>T p.E7156V | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV63456756; called by muse, mutect2, varscan2
- OLFML2A | c.308A>G p.E103G | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV59161941; called by muse, mutect2, varscan2
- OPA1 | c.248A>T p.Q83L | Missense Mutation (SNP) | VAF 17/243 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV62483344; called by muse, mutect2
- OPA1 | c.2239G>T p.E747* (on ENST00000361510 / NM_130837.3; = p.E692* on NM_015560.3) | Nonsense Mutation (SNP) | VAF 62/127 reads (49%) | catalogued as COSV62482219, COSV62483352; called by muse, mutect2, varscan2
- OR10A5 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 86/201 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV55055693; called by muse, mutect2, varscan2
- OR10Z1 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63526370; called by muse, varscan2
- OR1A1 | c.600C>A p.Y200* | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | catalogued as COSV58403171, COSV58404636; called by muse, mutect2, varscan2
- OR2F1 | c.560T>A p.L187Q | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67332071; called by muse, mutect2, varscan2
- OR2G3 | c.347C>A p.A116D | Missense Mutation (SNP) | VAF 185/262 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV60683142; called by mutect2, varscan2
- OR2M3 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 108/525 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.52); catalogued as COSV71759243, COSV71759267; called by muse, mutect2, varscan2
- OR2M7 | c.782A>T p.Q261L | Missense Mutation (SNP) | VAF 79/359 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as COSV58740683; called by muse, mutect2, varscan2
- OR4D2 | c.395A>G p.Y132C | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs1036912978, COSV73459872; called by muse, mutect2, varscan2
- OR6B1 | c.149T>A p.L50Q | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV68770648; called by muse, mutect2, varscan2
- OR6K2 | c.923A>G p.Q308R | Missense Mutation (SNP) | VAF 80/413 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV62744202; called by muse, mutect2, varscan2
- OR6T1 | c.62A>T p.H21L | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV58309482; called by muse, mutect2, varscan2
- OR8H2 | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV57943192; called by muse, mutect2, varscan2
- OR8K1 | c.260T>A p.M87K | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.366); catalogued as COSV54404223, COSV54404578; called by muse, mutect2, varscan2
- OSR1 | c.701A>G p.Q234R | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV55346516; called by muse, mutect2, varscan2
- OTOGL | c.5993A>T p.E1998V (on ENST00000547103; = p.E1989V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/258 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as COSV54023561; called by muse, mutect2, varscan2
- OXGR1 | c.413C>A p.P138Q | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472834802, COSV53658531; called by muse, mutect2, varscan2
- P2RY10 | c.926C>A p.A309D | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV50686187; called by muse, mutect2, varscan2
- P2RY6 | c.377T>A p.L126Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV62938216; called by muse, mutect2, varscan2
- P3H2 | c.1681T>C p.C561R | Missense Mutation (SNP) | VAF 103/236 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV60019946, COSV60027712; called by muse, mutect2, varscan2
- PAK5 | c.1766T>C p.F589S | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62037680; called by muse, mutect2, varscan2
- PARD3 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60761845; called by muse, mutect2, varscan2
- PARD3B | c.1621-2A>T p.X541_splice | Splice Site (SNP) | VAF 49/127 reads (39%) | catalogued as COSV62530263; called by muse, mutect2
- PCBP3 | c.218A>G p.E73G | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV68410082; called by muse, mutect2, varscan2
- PCDH11X | c.589A>T p.K197* | Nonsense Mutation (SNP) | VAF 203/457 reads (44%) | catalogued as COSV53503224; called by muse, mutect2, varscan2
- PCDH11X | c.3369T>A p.A1123= | Splice Region (SNP) | VAF 114/236 reads (48%) | catalogued as COSV53503263; called by muse, mutect2, varscan2
- PCDHA5 | c.934T>G p.Y312D | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as COSV65357699; called by muse, mutect2, varscan2
- PCDHB10 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53383703; called by muse, mutect2, varscan2
- PCDHB6 | c.2148G>T p.R716S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV50729322; called by muse, mutect2, varscan2
- PCDHB7 | c.611A>T p.E204V | Missense Mutation (SNP) | VAF 86/161 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.333); catalogued as COSV50815090; called by muse, mutect2, varscan2
- PCDHGA3 | c.272A>C p.D91A | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54030293; called by muse, varscan2
- PCLO | c.14107A>G p.N4703D | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs767862283, COSV61665384; called by muse, mutect2, varscan2
- PCLO | c.8984C>A p.S2995Y | Missense Mutation (SNP) | VAF 81/161 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61665408; called by muse, mutect2, varscan2
- PCLO | c.2141G>T p.G714V | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV61653970, COSV61665421; called by muse, mutect2, varscan2
- PDGFRA | c.2456T>G p.L819R | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57273740; called by muse, mutect2, varscan2
- PDPR | c.2408C>A p.A803D | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV55356473; called by muse, mutect2, varscan2
- PENK | c.482T>A p.L161Q | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59241146, COSV59243212; called by muse, mutect2, varscan2
- PHC1 | c.1067C>A p.T356K | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV70418668; called by muse, mutect2, varscan2
- PHF13 | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 88/244 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100885191; called by muse, varscan2
- PHF3 | c.334A>T p.R112W | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50340969; called by muse, mutect2, varscan2
- PHKB | c.942C>G p.S314R | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as rs775139159, COSV54520119, COSV54533880; called by muse, mutect2, varscan2
- PIK3R2 | c.1223A>G p.E408G | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV55850280; called by muse, mutect2, varscan2
- PIP5K1B | c.1358C>A p.A453D | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as COSV55257570; called by muse, mutect2, varscan2
- PKHD1L1 | c.10452C>G p.C3484W | Missense Mutation (SNP) | VAF 65/305 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs759444665, COSV101006893, COSV65752750; called by muse, mutect2, varscan2
- PLA2G3 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs866948115, COSV53212664; called by muse, mutect2, varscan2
- PLCB4 | c.50T>G p.L17W | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV53817664; called by muse, mutect2, varscan2
- PLD1 | c.1976A>G p.Q659R | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV60574062; called by muse, mutect2, varscan2
- PLIN4 | c.3300G>T p.K1100N (on ENST00000301286; = p.K1115N on NM_001367868.2) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV56698601; called by muse, mutect2, varscan2
- PNMA8A | c.77T>C p.L26S | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754215650, COSV58138995; called by muse, varscan2
- POU3F4 | c.795C>A p.S265R | Missense Mutation (SNP) | VAF 145/346 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV64541049; called by muse, mutect2, varscan2
- PPFIA2 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as COSV61053976; called by muse, mutect2, varscan2
- PPFIBP1 | c.1880T>A p.L627* (on ENST00000318304 / NM_177444.3; = p.L621* on NM_003622.4) | Nonsense Mutation (SNP) | VAF 38/73 reads (52%) | catalogued as COSV57298526; called by muse, mutect2, varscan2
- PPIG | c.350A>G p.K117R | Missense Mutation (SNP) | VAF 141/328 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as COSV53646078; called by muse, mutect2, varscan2
- PPP1R3F | c.2025A>G p.I675M | Missense Mutation (SNP) | VAF 92/106 reads (87%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50020374; called by muse, mutect2, varscan2
- PRAMEF12 | c.1379G>A p.G460D | Missense Mutation (SNP) | VAF 121/261 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV63216674; called by muse, mutect2, varscan2
- PREX2 | c.1048C>A p.H350N | Missense Mutation (SNP) | VAF 121/179 reads (68%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV55798201; called by muse, mutect2, varscan2
- PRKDC | c.11270A>T p.D3757V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100038951, COSV58063406; called by muse, mutect2, varscan2
- PRL | c.622C>A p.H208N | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV60593640; called by muse, mutect2, varscan2
- PRPF4B | c.2590A>G p.K864E | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.992); catalogued as COSV61785784; called by muse, mutect2, varscan2
- PRPS1L1 | c.772A>G p.I258V | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV72650013; called by muse, mutect2
- PRSS16 | c.283A>T p.I95L | Missense Mutation (SNP) | VAF 54/275 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs752229354, COSV57916913; called by muse, mutect2, varscan2
- PRTFDC1 | c.426T>A p.D142E | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs148662493; called by muse, mutect2
- PRTFDC1 | c.305T>C p.M102T | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.17); catalogued as rs368309249; called by muse, mutect2, varscan2
- PRTG | c.988G>T p.V330F | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.911); catalogued as COSV66840635; called by muse, varscan2
- PRUNE2 | c.1727G>T p.S576I | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100944648, COSV65047827; called by muse, mutect2, varscan2
- PSAP | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs779915400, COSV67551192; called by muse, mutect2, varscan2
- PSMA4 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.372); catalogued as COSV50385256; called by muse, mutect2, varscan2
- PTER | c.950T>C p.L317P | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54347475; called by muse, mutect2, varscan2
- PTH1R | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 86/96 reads (90%) | SIFT tolerated (0.05); PolyPhen benign (0.43); catalogued as COSV57317798; called by muse, mutect2, varscan2
- PTK7 | c.1772T>A p.F591Y | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57847542, COSV57851611; called by muse, mutect2, varscan2
- PTPN13 | c.7354C>A p.Q2452K (on ENST00000411767 / NM_080683.3; = p.Q2433K on NM_006264.3) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57417243; called by muse, mutect2, varscan2
- PTPRZ1 | c.3936T>A p.F1312L | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.014); catalogued as COSV66445380; called by muse, mutect2, varscan2
- PUS1 | c.455C>A p.A152D | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59036560; called by muse, mutect2, varscan2
- PXDNL | c.2756T>A p.L919H | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV62498224; called by muse, mutect2, varscan2
- QPCT | c.895T>A p.Y299N | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV58121268; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1171A>G p.S391G | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV50249783; called by muse, mutect2, varscan2
- RAB3IL1 | c.95A>G p.H32R | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV57118990; called by muse, mutect2, varscan2
- RAI1 | c.2663A>T p.Q888L | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.034); catalogued as COSV55399069; called by muse, mutect2, varscan2
- RAP1GAP | c.397A>T p.T133S | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV51578049; called by muse, mutect2, varscan2
- RAPGEF1 | c.97A>G p.K33E | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.872); catalogued as COSV64702279; called by muse, mutect2, varscan2
- RARA | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV54196870; called by muse, mutect2, varscan2
- RASSF8 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as COSV51455310; called by muse, mutect2, varscan2
- RBAK-RBAKDN | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as COSV67760912; called by muse, mutect2, varscan2
- RBL1 | c.2995A>T p.R999* | Nonsense Mutation (SNP) | VAF 93/215 reads (43%) | catalogued as COSV60333649; called by muse, mutect2, varscan2
- RBL2 | c.3215A>C p.K1072T | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as COSV50888113; called by muse, mutect2, varscan2
- RDH8 | c.424G>T p.V142F (on ENST00000651512; = p.V122F on NM_015725.4) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50674418, COSV50675592, COSV50678474; called by muse, mutect2, varscan2
- RGS20 | c.8A>T p.Q3L | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV52022291; called by muse, mutect2, varscan2
- RIMS1 | c.856C>G p.L286V | Missense Mutation (SNP) | VAF 121/265 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV53484034; called by muse, mutect2, varscan2
- RNF214 | c.187A>T p.R63* | Nonsense Mutation (SNP) | VAF 56/131 reads (43%) | catalogued as COSV56121016; called by muse, mutect2, varscan2
- RNF216 | c.1514A>C p.Q505P (on ENST00000425013 / NM_207116.3; = p.Q562P on NM_207111.4) | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV66292665; called by muse, mutect2
- RNF8 | c.1394G>T p.S465I | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV57722265; called by muse, mutect2, varscan2
- ROBO1 | c.3315G>T p.Q1105H | Missense Mutation (SNP) | VAF 88/299 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV71397749, COSV71398509; called by muse, mutect2, varscan2
- ROBO1 | c.2018T>A p.L673Q | Missense Mutation (SNP) | VAF 78/266 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71398510; called by muse, mutect2, varscan2
- ROR1 | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV64293181; called by muse, mutect2, varscan2
- RP1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 86/131 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs769522856, COSV55126509; called by muse, mutect2, varscan2
- RP1L1 | c.5960A>T p.Q1987L | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV66760177; called by muse, mutect2, varscan2
- RPL27 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV53815502; called by muse, mutect2, varscan2
- RTN4IP1 | c.58T>C p.W20R | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV64688137; called by muse, mutect2
- RUFY2 | c.1187A>T p.N396I | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56260958; called by muse, mutect2, varscan2
- RYR2 | c.2486A>T p.K829I | Missense Mutation (SNP) | VAF 188/260 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV63712826; called by muse, varscan2
- RYR2 | c.12946G>T p.G4316* | Nonsense Mutation (SNP) | VAF 118/180 reads (66%) | catalogued as COSV63684982; called by muse, varscan2
- SCN1A | c.2207C>T p.P736L (on ENST00000303395 / NM_001202435.3; = p.P725L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); catalogued as COSV57663231; called by muse, mutect2, varscan2
- SCNN1D | c.819-2A>T p.X273_splice (on ENST00000338555; = p.X437_splice on NM_001130413.4) | Splice Site (SNP) | VAF 23/68 reads (34%) | catalogued as COSV57644424; called by muse, mutect2, varscan2
- SEC23B | c.140A>G p.E47G | Missense Mutation (SNP) | VAF 102/228 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV52723825; called by muse, mutect2, varscan2
- SEMA4F | c.197C>A p.S66Y | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60285258; called by muse, mutect2, varscan2
- SERPINE2 | c.200T>A p.L67Q | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV51460071; called by muse, mutect2, varscan2
- SERPINI2 | c.572A>T p.Q191L | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as COSV52988800; called by muse, mutect2, varscan2
- SERTAD4 | c.294C>A p.T98= | Splice Region (SNP) | VAF 27/169 reads (16%) | catalogued as COSV100882630; called by muse, mutect2, varscan2
- SEZ6L | c.1478T>C p.L493P | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50686469; called by muse, mutect2, varscan2
- SIGLEC1 | c.3190G>A p.V1064I | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as COSV52472563; called by muse, mutect2, varscan2
- SIGLEC7 | c.245A>T p.N82I | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); catalogued as COSV58317822; called by muse, mutect2
- SLC16A9 | c.130T>C p.F44L | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV68100593; called by muse, mutect2
- SLC1A6 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 42/94 reads (45%) | catalogued as COSV55673929; called by muse, mutect2, varscan2
- SLC23A2 | c.1825A>G p.I609V | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1242736840, COSV57779879; called by muse, varscan2
- SLC30A1 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.328); catalogued as COSV65361578; called by muse, mutect2, varscan2
- SLC37A3 | c.916A>G p.N306D | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58268560; called by muse, mutect2, varscan2
- SLC4A1 | c.2342C>T p.S781F | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV52263067; called by muse, mutect2, varscan2
- SLC6A3 | c.1339C>A p.L447I | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0.378); catalogued as COSV54369439; called by muse, mutect2, varscan2
- SLC6A4 | c.1609T>A p.W537R | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55569696; called by muse, mutect2, varscan2
- SLC6A5 | c.1558A>C p.I520L | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54232326; called by muse, mutect2, varscan2
- SLC9C2 | c.1215G>T p.M405I | Missense Mutation (SNP) | VAF 91/425 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.138); catalogued as COSV62949449; called by muse, mutect2, varscan2
- SLFN13 | c.2398T>A p.F800I | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV53195604; called by muse, mutect2, varscan2
- SLIT2 | c.62A>G p.N21S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1489371040, COSV56594943; called by muse, mutect2, varscan2
- SLIT2 | c.1188C>A p.H396Q | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56594954; called by muse, mutect2
- SLITRK6 | c.1844T>G p.L615R | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68391683; called by muse, mutect2, varscan2
- SMG9 | c.917A>T p.Q306L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54216374; called by muse, mutect2, varscan2
- SMOX | c.191T>C p.V64A | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53868253; called by muse, mutect2, varscan2
- SOHLH1 | c.416A>T p.Q139L | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV53683936; called by muse, mutect2, varscan2
- SOX12 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61258690, COSV61259229; called by muse, mutect2, varscan2
- SPATA22 | c.755A>G p.Y252C | Missense Mutation (SNP) | VAF 149/388 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52154697; called by muse, mutect2, varscan2
- SPATA45 | c.175A>C p.T59P | Missense Mutation (SNP) | VAF 194/276 reads (70%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV60572764; called by mutect2, varscan2
- SPATA5L1 | c.276G>C p.R92S | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV59745615; called by muse, mutect2, varscan2
- SPOCK3 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.119); catalogued as COSV62736978; called by muse, mutect2, varscan2
- SPTA1 | c.2248G>C p.A750P | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1160893585, COSV63759209; called by muse, mutect2
- SRCAP | c.8366G>A p.G2789E | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as rs1361660421, COSV52681010, COSV52681157; called by muse, mutect2, varscan2
- SRRM4 | c.412A>T p.S138C | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.74); catalogued as rs1165077731, COSV57427016; called by muse, mutect2, varscan2
- STAB1 | c.5729G>T p.R1910L | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT tolerated (0.44); PolyPhen benign (0.025); catalogued as COSV58733082, COSV58742914; called by muse, mutect2, varscan2
- STEAP3 | c.1244G>T p.W415L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100713316, COSV61531022; called by muse, mutect2, varscan2
- STK35 | c.1492A>G p.M498V | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.089); catalogued as COSV55692833; called by muse, mutect2, varscan2
- STMN2 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55222493; called by muse, mutect2
- SUFU | c.214A>T p.S72C | Missense Mutation (SNP) | VAF 82/121 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64016303; called by muse, mutect2, varscan2
- SVEP1 | c.9407A>T p.E3136V | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.339); catalogued as COSV52844044; called by muse, mutect2, varscan2
- SVEP1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57047722; called by muse, mutect2, varscan2
- SYNE2 | c.8834G>A p.C2945Y | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59969568; called by muse, mutect2, varscan2
- SYT3 | c.1434G>T p.E478D | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58898996; called by muse, mutect2, varscan2
- TCF4 | c.77A>T p.Y26F | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious, low confidence (0); catalogued as COSV68172969; called by muse, mutect2, varscan2
- TCHH | c.4451A>G p.D1484G | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV64277660; called by muse, mutect2, varscan2
- TCN1 | c.866A>T p.Q289L | Missense Mutation (SNP) | VAF 65/253 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57254689; called by muse, mutect2, varscan2
- TDRD9 | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59155939; called by muse, mutect2, varscan2
- TEK | c.2171C>A p.A724D | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.089); catalogued as COSV66234428; called by muse, mutect2, varscan2
- TENM3 | c.3350A>G p.D1117G | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1290685286, COSV69319016; called by muse, mutect2, varscan2
- TEX11 | c.2513T>A p.L838Q (on ENST00000344304; = p.L823Q on NM_031276.3) | Missense Mutation (SNP) | VAF 204/443 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV60239065; called by muse, mutect2, varscan2
- TEX55 | c.947A>G p.E316G | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV55212900; called by muse, mutect2, varscan2
- THAP12 | c.941T>A p.I314K | Missense Mutation (SNP) | VAF 122/328 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV52613064; called by muse, mutect2, varscan2
- THOP1 | c.1456-2A>T p.X486_splice | Splice Site (SNP) | VAF 18/42 reads (43%) | catalogued as COSV57021085; called by muse, mutect2, varscan2
- THRSP | c.86A>G p.Q29R | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55246935; called by muse, mutect2, varscan2
- TMEM132B | c.2584A>G p.K862E | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV54769394; called by muse, mutect2, varscan2
- TMEM179 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs779256818, COSV58796410; called by muse, mutect2, varscan2
- TMEM79 | c.742T>A p.F248I | Missense Mutation (SNP) | VAF 88/133 reads (66%) | SIFT tolerated (0.42); PolyPhen benign (0.097); catalogued as rs1459826629, COSV55297624; called by muse, mutect2, varscan2
- TMF1 | c.802A>G p.I268V | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.107); catalogued as rs762003130, COSV68374090; called by muse, mutect2, varscan2
- TMPRSS11A | c.458T>C p.L153S | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV58361094; called by muse, mutect2, varscan2
- TNN | c.463T>A p.C155S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV99512181; called by muse, mutect2
- TNNI3K | c.1774C>A p.H592N | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); catalogued as COSV58565728, COSV58565779; called by muse, mutect2, varscan2
- TNPO1 | c.1801G>T p.V601F | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV61523914; called by muse, mutect2, varscan2
- TNPO1 | c.2665A>G p.K889E | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV61523921; called by muse, mutect2, varscan2
- TNRC6B | c.4639G>T p.A1547S (on ENST00000454349 / NM_001162501.2; = p.A1437S on NM_015088.3) | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.978); catalogued as COSV57307438; called by muse, mutect2, varscan2
- TNS1 | c.706A>G p.I236V | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50766231; called by muse, mutect2, varscan2
- TNS3 | c.3271A>T p.T1091S | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60799180; called by muse, mutect2, varscan2
- TPBG | c.266T>A p.L89Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63883101; called by muse, mutect2, varscan2
- TRHR | c.380T>G p.I127S | Missense Mutation (SNP) | VAF 74/394 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61236472; called by muse, mutect2, varscan2
- TRIM28 | c.545A>G p.Q182R | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.988); catalogued as COSV53401761; called by muse, mutect2, varscan2
- TRPA1 | c.2938-2A>T p.X980_splice | Splice Site (SNP) | VAF 57/108 reads (53%) | catalogued as COSV51573821; called by muse, mutect2, varscan2
- TRPC6 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV60258454, COSV60260905; called by muse, mutect2, varscan2
- TSNAX | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 237/348 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64145665, COSV64147027, COSV64147189; called by muse, mutect2, varscan2
- TSPOAP1 | c.4996A>G p.K1666E | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52117626; called by muse, mutect2, varscan2
- TTC25 | c.1840A>G p.R614G | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV66367864; called by muse, mutect2, varscan2
- TTC6 | c.781G>T p.E261* (on ENST00000267368; = p.E1627* on NM_001310135.3) | Nonsense Mutation (SNP) | VAF 51/109 reads (47%) | catalogued as COSV99941949; called by muse, mutect2, varscan2
- TTK | c.2048A>G p.Q683R | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV57886807; called by muse, mutect2, varscan2
- TTN | c.32749C>A p.P10917T (on ENST00000591111; = p.P9990T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/128 reads (34%) | PolyPhen benign (0.275); catalogued as COSV60341611; called by muse, mutect2, varscan2
- TTN | c.21446A>C p.Q7149P (on ENST00000591111; = p.Q6222P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/97 reads (39%) | PolyPhen benign (0.172); catalogued as COSV60341619; called by muse, mutect2, varscan2
- TUBB2B | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52534434; called by muse, mutect2, varscan2
- TUT7 | c.526A>G p.K176E | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs774811677, COSV52898862; called by muse, mutect2, varscan2
- TYR | c.8T>A p.L3Q | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV54485907; called by muse, mutect2, varscan2
- U2AF2 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV58275946, COSV58276201, COSV58276501; called by muse, mutect2, varscan2
- UBL4B | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 36/94 reads (38%) | catalogued as COSV61944465; called by muse, mutect2, varscan2
- ULK1 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV58859876; called by muse, mutect2, varscan2
- UMODL1 | c.86T>A p.L29H | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68577948; called by muse, mutect2, varscan2
- UNC79 | c.2633T>A p.L878Q (on ENST00000393151 / NM_001346218.2; = p.L701Q on NM_020818.5) | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56409818; called by muse, mutect2, varscan2
- USP7 | c.3045G>T p.E1015D | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.395); catalogued as COSV61217442; called by muse, mutect2, varscan2
- UTP15 | c.683A>G p.Y228C | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); catalogued as COSV57147604; called by muse, mutect2, varscan2
- UTP25 | c.1487A>G p.H496R | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71966182; called by muse, mutect2, varscan2
- VPS35L | c.1460A>C p.N487T | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV51991302; called by muse, mutect2, varscan2
- VRTN | c.1935G>T p.M645I | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV56443614; called by muse, mutect2, varscan2
- VWA3B | c.1271T>C p.I424T | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV68246661; called by muse, mutect2, varscan2
- VWA7 | c.1568G>T p.G523V | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV65174160; called by muse, mutect2, varscan2
- WDR43 | c.1829A>T p.D610V | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV68019592; called by muse, mutect2, varscan2
- WDR47 | c.2155G>A p.G719S (on ENST00000369962 / NM_001142551.2; = p.G720S on NM_014969.5) | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.202); catalogued as COSV63059795; called by muse, mutect2, varscan2
- WDR70 | c.1461G>A p.M487I | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1289414446, COSV54283647; called by muse, mutect2, varscan2
- WFDC3 | c.445T>A p.C149S | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54786319; called by muse, mutect2, varscan2
- WFDC3 | c.61T>A p.W21R | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.213); catalogued as COSV54786327; called by muse, mutect2, varscan2
- WNT4 | c.976T>C p.C326R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51605532; called by muse, mutect2, varscan2
- YIF1B | c.598G>A p.E200K (on ENST00000339413 / NM_001039673.3; = p.E185K on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56651768; called by muse, varscan2
- ZBED2 | c.358C>A p.Q120K | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV51922895; called by muse, mutect2, varscan2
- ZBTB39 | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.109); catalogued as COSV100268012, COSV55630859; called by muse, mutect2, varscan2
- ZFP36L1 | c.832C>A p.L278I | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.194); catalogued as COSV60547196; called by muse, mutect2, varscan2
- ZFPM2 | c.1268G>A p.S423N | Missense Mutation (SNP) | VAF 129/286 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.494); catalogued as rs377466426; called by muse, mutect2, varscan2
- ZFYVE9 | c.3333A>G p.A1111= | Splice Region (SNP) | VAF 39/95 reads (41%) | catalogued as rs1174780592, COSV55100101; called by muse, mutect2, varscan2
- ZGPAT | c.1016G>T p.R339I | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV58873754; called by muse, mutect2, varscan2
- ZIM3 | c.1327G>T p.G443* | Nonsense Mutation (SNP) | VAF 48/123 reads (39%) | catalogued as COSV54146533, COSV54146572; called by muse, mutect2, varscan2
- ZMYND15 | c.2123C>A p.A708E (on ENST00000433935 / NM_001136046.3; = p.A669E on NM_032265.2) | Missense Mutation (SNP) | VAF 116/228 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV52644908; called by muse, mutect2, varscan2
- ZNF256 | c.1454A>G p.H485R | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1172081536, COSV56599647; called by muse, mutect2, varscan2
- ZNF264 | c.1869A>T p.Q623H | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV99567212; called by muse, mutect2
- ZNF28 | c.1550A>G p.H517R | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs369691107; called by muse, mutect2, varscan2
- ZNF285 | c.224A>C p.Q75P | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV58411176; called by muse, mutect2, varscan2
- ZNF311 | c.1894A>G p.R632G | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV65853409; called by muse, mutect2, varscan2
- ZNF330 | c.121-2A>T p.X41_splice | Splice Site (SNP) | VAF 146/334 reads (44%) | catalogued as COSV53708468; called by muse, mutect2, varscan2
- ZNF451 | c.1087T>A p.Y363N | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV62600024; called by muse, varscan2
- ZNF451 | c.1088A>T p.Y363F | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.071); catalogued as COSV62600035; called by muse, varscan2
- ZNF473 | c.1339A>G p.N447D | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.182); catalogued as COSV54525074; called by muse, mutect2, varscan2
- ZNF479 | c.1008G>T p.W336C | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1554400081, COSV100482578, COSV100482758, COSV100482804; called by muse, varscan2
- ZNF479 | c.1007G>T p.W336L | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs373275999; called by muse, varscan2
- ZNF483 | c.4C>A p.Q2K | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV58517265; called by muse, mutect2
- ZNF521 | c.2254T>A p.Y752N | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64131824; called by muse, mutect2, varscan2
- ZNF676 | c.202C>A p.H68N (on ENST00000650058; = p.H36N on NM_001001411.3) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.607); catalogued as rs1481320780, COSV68094901; called by muse, mutect2
- ZNF683 | c.125C>G p.A42G | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV62875864; called by muse, mutect2, varscan2
- ZNF707 | c.724A>G p.S242G | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV62311733; called by muse, mutect2
- ZNF708 | c.687T>A p.C229* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV63608801; called by muse, mutect2, varscan2
- ZNF786 | c.2302A>G p.K768E | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV60277641; called by muse, mutect2, varscan2
- ACSM5 | c.711dup p.K238Qfs*28 | Frame Shift Ins (INS) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- ARHGEF19 | c.961del p.A321Pfs*50 | Frame Shift Del (DEL) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- ASXL1 | c.3046_3067del p.A1016* | Frame Shift Del (DEL) | VAF 25/67 reads (37%) | called by mutect2, pindel, varscan2
- C9orf50 | c.1103_1112del p.P368Hfs*39 | Frame Shift Del (DEL) | VAF 38/98 reads (39%) | called by mutect2, pindel, varscan2
- CCDC83 | c.716_760del p.I239_S254delinsT | In Frame Del (DEL) | VAF 60/200 reads (30%) | called by mutect2, pindel
- CCL14 | c.166A>G p.N56D (on ENST00000618404 / NM_032963.4; = p.N72D on NM_032962.4) | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- DGAT1 | c.1248_1248+1dup p.X416_splice | Splice Site (INS) | VAF 50/117 reads (43%) | called by mutect2, pindel, varscan2
- IFIT5 | c.4_5dup p.S2? | Frame Shift Ins (INS) | VAF 42/81 reads (52%) | called by mutect2, pindel, varscan2
- IGLV3-19 | c.79C>G p.P27A | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- JPH2 | c.1903G>T p.A635S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2
- LGSN | c.1122_1124del p.K374_D375delinsN | In Frame Del (DEL) | VAF 35/70 reads (50%) | called by mutect2, pindel, varscan2
- LMBRD1 | c.1073del p.G358Efs*2 (on ENST00000649011; = p.G336Efs*2 on NM_018368.4) | Frame Shift Del (DEL) | VAF 87/245 reads (36%) | called by mutect2, pindel, varscan2
- MEN1 | c.975del p.Y326Tfs*47 | Frame Shift Del (DEL) | VAF 63/86 reads (73%) | called by mutect2, varscan2
- MUC2 | c.3433T>C p.C1145R | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- NCSTN | c.178_181del p.I60Afs*15 | Frame Shift Del (DEL) | VAF 106/167 reads (63%) | called by mutect2, pindel, varscan2
- NSUN4 | c.352_353insT p.P118Lfs*18 | Frame Shift Ins (INS) | VAF 31/89 reads (35%) | called by mutect2, pindel, varscan2
- OR2F2 | c.934del p.T312Hfs*9 | Frame Shift Del (DEL) | VAF 25/56 reads (45%) | called by mutect2, varscan2
- SHOC2 | c.652del p.S218Afs*28 | Frame Shift Del (DEL) | VAF 37/136 reads (27%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.2403G>T p.Q801H | Missense Mutation (SNP) | VAF 59/69 reads (86%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- TRPM2 | c.1545del p.W516Gfs*87 | Frame Shift Del (DEL) | VAF 34/88 reads (39%) | called by mutect2, varscan2
- XPO6 | c.1635_1643del p.N545_R548delinsK | In Frame Del (DEL) | VAF 20/51 reads (39%) | called by mutect2, pindel, varscan2
- ZNF492 | c.721A>T p.T241S | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.03); called by muse, mutect2
- ZNF687 | c.2997dup p.R1000Afs*16 | Frame Shift Ins (INS) | VAF 28/163 reads (17%) | called by mutect2, pindel, varscan2
- A2ML1 | c.900C>T p.T300= | Silent (SNP) | VAF 46/104 reads (44%) | catalogued as COSV55295338, COSV55298371; called by muse, mutect2, varscan2
- ABCA12 | c.5742T>C p.D1914= (on ENST00000272895 / NM_173076.3; = p.D1596= on NM_015657.3) | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as rs775639136, COSV55975048; called by muse, mutect2, varscan2
- ABCC4 | c.990C>A p.I330= | Silent (SNP) | VAF 54/114 reads (47%) | catalogued as COSV65318185; called by muse, mutect2, varscan2
- ACAP2 | c.87A>T p.A29= | Silent (SNP) | VAF 277/720 reads (38%) | catalogued as COSV58755788; called by muse, mutect2, varscan2
- ACKR1 | c.903C>G p.P301= | Silent (SNP) | VAF 94/137 reads (69%) | catalogued as COSV63673332, COSV63674542; called by muse, varscan2
- ACOXL | c.480T>A p.V160= | Silent (SNP) | VAF 59/114 reads (52%) | catalogued as COSV61330613; called by muse, mutect2, varscan2
- ADTRP | c.243C>T p.A81= | Silent (SNP) | VAF 54/247 reads (22%) | catalogued as COSV57645792; called by muse, mutect2, varscan2
- ALDH1A3 | c.820C>T p.L274= | Silent (SNP) | VAF 20/152 reads (13%) | catalogued as COSV60903261; called by muse, mutect2, varscan2
- ALS2 | c.2661G>A p.K887= | Silent (SNP) | VAF 85/158 reads (54%) | catalogued as COSV51892465; called by muse, mutect2, varscan2
- ANKRD26 | c.4305A>G p.L1435= | Silent (SNP) | VAF 90/151 reads (60%) | catalogued as rs975527692, COSV65778274; called by muse, mutect2, varscan2
- APLP1 | c.1764C>A p.I588= (on ENST00000221891 / NM_001024807.3; = p.I587= on NM_005166.4) | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV55706865, COSV99697766; called by muse, mutect2, varscan2
- ARL6IP1 | c.93G>A p.L31= | Silent (SNP) | VAF 47/114 reads (41%) | catalogued as COSV58614956; called by muse, mutect2, varscan2
- ASAH1 | c.150A>T p.S50= | Silent (SNP) | VAF 52/64 reads (81%) | catalogued as COSV50504537; called by muse, mutect2, varscan2
- ASZ1 | c.1308T>C p.H436= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV52916375; called by muse, mutect2, varscan2
- B3GALNT1 | c.669T>C p.H223= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV57581178; called by muse, mutect2, varscan2
- BICRA | c.2199A>T p.P733= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV101194359; called by muse, mutect2, varscan2
- BOC | c.1389A>T p.P463= | Silent (SNP) | VAF 58/122 reads (48%) | catalogued as COSV56357876; called by muse, mutect2, varscan2
- BRDT | c.171T>C p.D57= | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as COSV61771564; called by muse, mutect2, varscan2
- BRINP3 | c.2112A>T p.L704= | Silent (SNP) | VAF 63/289 reads (22%) | catalogued as COSV66541032; called by muse, mutect2, varscan2
- BTF3 | c.348C>A p.I116= (on ENST00000380591 / NM_001037637.1; = p.I72= on NM_001207.4) | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV60063898; called by muse, mutect2, varscan2
- C11orf65 | c.648T>C p.A216= | Silent (SNP) | VAF 73/199 reads (37%) | catalogued as COSV67598627; called by muse, varscan2
- C20orf194 | c.2184T>C p.P728= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs1353317823, COSV52702679; called by muse, mutect2, varscan2
- CAMSAP2 | c.1881A>T p.S627= (on ENST00000236925 / NM_001297707.2; = p.S616= on NM_203459.3) | Silent (SNP) | VAF 40/208 reads (19%) | catalogued as COSV52677236; called by muse, mutect2, varscan2
- CAND2 | c.1794T>A p.L598= (on ENST00000456430 / NM_001162499.2; = p.L505= on NM_012298.3) | Silent (SNP) | VAF 101/118 reads (86%) | catalogued as COSV55994443; called by muse, mutect2, varscan2
- CATSPERB | c.1395T>C p.F465= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV56435156; called by muse, mutect2, varscan2
- CATSPERE | c.507T>G p.V169= | Silent (SNP) | VAF 132/589 reads (22%) | catalogued as rs757293745, COSV63681914; called by muse, mutect2, varscan2
- CDHR1 | c.1479T>A p.A493= | Silent (SNP) | VAF 39/129 reads (30%) | catalogued as COSV60566387; called by muse, mutect2, varscan2
- CDON | c.258T>C p.S86= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV55002461; called by muse, mutect2, varscan2
- CEACAM1 | c.1569A>G p.V523= | Silent (SNP) | VAF 58/118 reads (49%) | catalogued as COSV50732810; called by muse, mutect2, varscan2
- CEP131 | c.1719G>C p.V573= (on ENST00000269392 / NM_001319228.2; = p.V570= on NM_014984.4) | Silent (SNP) | VAF 100/220 reads (45%) | catalogued as COSV53956263; called by muse, mutect2, varscan2
- CFAP61 | c.1158T>A p.A386= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV55647188; called by muse, mutect2, varscan2
- CIT | c.624T>A p.A208= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as COSV55882899; called by muse, mutect2, varscan2
- CLVS2 | c.342T>C p.Y114= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV51568914; called by muse, mutect2, varscan2
- COASY | c.441G>C p.L147= | Silent (SNP) | VAF 52/104 reads (50%) | catalogued as COSV55900435; called by muse, mutect2, varscan2
- COL11A1 | c.2457A>T p.A819= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV62196966; called by muse, mutect2, varscan2
- COL1A2 | c.1242T>C p.A414= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV51966010; called by muse, mutect2, varscan2
- COL20A1 | c.2601T>C p.S867= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV58927152; called by muse, mutect2, varscan2
- COL4A4 | c.4203C>T p.G1401= | Silent (SNP) | VAF 100/236 reads (42%) | catalogued as COSV61636491; called by muse, mutect2, varscan2
- COL4A6 | c.165T>C p.I55= | Silent (SNP) | VAF 69/147 reads (47%) | catalogued as COSV57877839; called by muse, mutect2, varscan2
- CPED1 | c.1881G>T p.G627= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as COSV60013033, COSV60014162; called by muse, mutect2, varscan2
- CR2 | c.1587A>T p.P529= | Silent (SNP) | VAF 38/132 reads (29%) | catalogued as COSV65509591; called by muse, mutect2, varscan2
- CSPP1 | c.84A>T p.R28= | Silent (SNP) | VAF 65/109 reads (60%) | catalogued as COSV51592511; called by muse, mutect2, varscan2
- DCN | c.669T>A p.L223= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV50009256; called by muse, mutect2, varscan2
- DENND2A | c.1195T>C p.L399= | Silent (SNP) | VAF 47/123 reads (38%) | catalogued as COSV52053945, COSV52058804; called by muse, mutect2, varscan2
- DGKK | c.2613T>C p.S871= | Silent (SNP) | VAF 64/72 reads (89%) | catalogued as COSV65709383; called by mutect2, varscan2
- DHX9 | c.1512A>T p.G504= | Silent (SNP) | VAF 32/157 reads (20%) | catalogued as rs879126123, COSV62362142; called by muse, mutect2, varscan2
- DIPK2A | c.1182G>A p.R394= | Silent (SNP) | VAF 65/132 reads (49%) | catalogued as COSV100237498, COSV59858443; called by muse, varscan2
- DISC1 | c.150A>T p.T50= | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as COSV54418625; called by muse, mutect2, varscan2
- DNAH2 | c.1518G>A p.R506= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV50020460; called by muse, mutect2, varscan2
- DNAH8 | c.13146T>A p.V4382= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV59479664; called by muse, mutect2, varscan2
- DNASE1L1 | c.162G>A p.V54= | Silent (SNP) | VAF 107/208 reads (51%) | catalogued as rs150301252, COSV50011193; called by muse, mutect2, varscan2
- DRC7 | c.1797C>A p.P599= | Silent (SNP) | VAF 108/224 reads (48%) | catalogued as COSV61057736; called by muse, mutect2, varscan2
- DTX2 | c.882A>T p.P294= | Silent (SNP) | VAF 54/134 reads (40%) | catalogued as COSV56865054; called by muse, mutect2, varscan2
- DZIP1 | c.2478G>T p.V826= (on ENST00000347108; = p.V807= on NM_014934.5) | Silent (SNP) | VAF 48/115 reads (42%) | catalogued as COSV61270062; called by muse, mutect2, varscan2
- ELMOD1 | c.828A>G p.T276= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as COSV56196404; called by muse, mutect2, varscan2
- EMD | c.66G>T p.P22= | Silent (SNP) | VAF 42/93 reads (45%) | catalogued as COSV63962505; called by muse, mutect2, varscan2
- ENO2 | c.378G>C p.R126= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV50396238; called by muse, mutect2, varscan2
- ENPP3 | c.1179A>T p.I393= | Silent (SNP) | VAF 82/173 reads (47%) | catalogued as COSV62956654; called by muse, mutect2, varscan2
- EPHB6 | c.1095C>T p.A365= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV67420796; called by muse, mutect2, varscan2
- ERICH3 | c.2301T>C p.Y767= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as COSV58618133; called by muse, mutect2, varscan2
- FAM83B | c.2031T>C p.P677= | Silent (SNP) | VAF 110/498 reads (22%) | catalogued as COSV60926691; called by muse, varscan2
- FCGR2A | c.522C>T p.I174= (on ENST00000271450 / NM_001136219.3; = p.I173= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 228/1198 reads (19%) | catalogued as COSV54840648; called by muse, varscan2
- FCRL6 | c.756A>G p.S252= | Silent (SNP) | VAF 95/137 reads (69%) | catalogued as COSV58942628; called by muse, mutect2, varscan2
- FN3KRP | c.84C>T p.G28= | Silent (SNP) | VAF 193/420 reads (46%) | catalogued as rs777739924, COSV53931668; called by muse, varscan2
- FZD3 | c.1158G>C p.G386= | Silent (SNP) | VAF 45/64 reads (70%) | catalogued as COSV53537802; called by muse, mutect2, varscan2
- GEMIN5 | c.537T>C p.I179= | Silent (SNP) | VAF 65/149 reads (44%) | catalogued as COSV53564774; called by muse, mutect2, varscan2
- GIT2 | c.561A>G p.A187= | Silent (SNP) | VAF 67/159 reads (42%) | catalogued as COSV58085104; called by muse, mutect2, varscan2
- GK5 | c.1503A>G p.P501= | Silent (SNP) | VAF 54/134 reads (40%) | catalogued as rs1465090258, COSV67486769; called by muse, mutect2, varscan2
- GLI2 | c.2016G>T p.G672= (on ENST00000361492 / NM_001374353.1; = p.G689= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/130 reads (48%) | catalogued as COSV58051238, COSV58052541; called by muse, mutect2, varscan2
- GPR22 | c.156T>A p.I52= | Silent (SNP) | VAF 80/187 reads (43%) | catalogued as COSV51764273; called by muse, mutect2, varscan2
- GPR45 | c.78C>A p.S26= | Silent (SNP) | VAF 47/115 reads (41%) | catalogued as COSV51523232, COSV51526201; called by muse, mutect2, varscan2
- GPR89B | c.48A>T p.L16= | Silent (SNP) | VAF 84/355 reads (24%) | catalogued as COSV58502248; called by muse, mutect2, varscan2
- GRIK5 | c.1953T>C p.P651= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV53485552; called by muse, mutect2, varscan2
- GTSE1 | c.1494G>T p.T498= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV71889799; called by muse, mutect2, varscan2
- H2BC11 | c.336G>T p.V112= | Silent (SNP) | VAF 33/165 reads (20%) | catalogued as COSV60362760; called by muse, mutect2, varscan2
- HPS4 | c.1362C>G p.P454= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV61105690; called by muse, mutect2, varscan2
- HS6ST1 | c.858G>A p.R286= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV99389262, COSV99389662; called by muse, mutect2, varscan2
- IGHG1 | c.543C>T p.S181= | Silent (SNP) | VAF 68/144 reads (47%) | called by muse, mutect2, varscan2
- IGSF10 | c.5934A>G p.P1978= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as COSV56791525; called by muse, mutect2, varscan2
- IGSF9B | c.636C>T p.S212= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV58072689; called by muse, mutect2, varscan2
- IKZF1 | c.1182C>T p.C394= | Silent (SNP) | VAF 42/84 reads (50%) | catalogued as COSV58791506; called by muse, mutect2, varscan2
- INTS1 | c.5760G>T p.P1920= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs769069843, COSV67178744; called by muse, mutect2, varscan2
- ITGA9 | c.2145A>C p.S715= | Silent (SNP) | VAF 58/68 reads (85%) | catalogued as COSV53252632; called by muse, mutect2, varscan2
- KAT6A | c.2586A>G p.P862= | Silent (SNP) | VAF 22/31 reads (71%) | catalogued as rs1378871985, COSV55911868; called by muse, mutect2, varscan2
- KERA | c.933A>C p.A311= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV57131842; called by muse, varscan2
- KIAA1549L | c.4155A>T p.A1385= (on ENST00000321505; = p.A1682= on NM_012194.3) | Silent (SNP) | VAF 44/111 reads (40%) | catalogued as COSV58596098; called by muse, mutect2, varscan2
- KIF4A | c.1458A>G p.A486= | Silent (SNP) | VAF 71/140 reads (51%) | catalogued as COSV65545799; called by muse, mutect2, varscan2
- KIF6 | c.1761T>A p.S587= | Silent (SNP) | VAF 35/159 reads (22%) | catalogued as COSV54694113; called by muse, mutect2, varscan2
- LHX3 | c.1020A>C p.P340= (on ENST00000371748 / NM_178138.6; = p.P345= on NM_014564.5) | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as COSV65583377; called by muse, varscan2
- LILRB3 | c.1812T>C p.D604= (on ENST00000346401; = p.D592= on NM_006864.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 74/155 reads (48%) | catalogued as rs1443024560, COSV54446550; called by muse, mutect2, varscan2
- LIPI | c.1353A>G p.P451= | Silent (SNP) | VAF 78/222 reads (35%) | catalogued as COSV60716038; called by muse, mutect2, varscan2
- LMX1B | c.816A>T p.A272= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV62741870; called by muse, mutect2, varscan2
- LRFN5 | c.570C>A p.T190= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as COSV53274732; called by muse, mutect2, varscan2
- LRRC4B | c.762C>T p.S254= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV65350787; called by muse, mutect2, varscan2
- LRRK1 | c.4101C>A p.A1367= | Silent (SNP) | VAF 54/119 reads (45%) | catalogued as COSV52625780; called by muse, mutect2, varscan2
- LRRK2 | c.7413G>A p.L2471= | Silent (SNP) | VAF 130/330 reads (39%) | catalogued as COSV54170116; called by muse, varscan2
- LTBP4 | c.4434C>T p.D1478= (on ENST00000308370 / NM_001042544.1; = p.D1441= on NM_003573.2) | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs766181550, COSV52575654; called by muse, mutect2, varscan2
- MAGEC3 | c.714C>T p.G238= | Silent (SNP) | VAF 59/137 reads (43%) | catalogued as COSV71610244; called by muse, mutect2, varscan2
- MAGEE2 | c.438T>C p.V146= | Silent (SNP) | VAF 48/105 reads (46%) | catalogued as COSV64898489; called by muse, mutect2, varscan2
- MAP2 | c.858T>A p.P286= | Silent (SNP) | VAF 56/131 reads (43%) | catalogued as COSV52307587; called by muse, mutect2, varscan2
- MAP3K12 | c.985C>T p.L329= | Silent (SNP) | VAF 48/115 reads (42%) | catalogued as COSV57235982; called by muse, mutect2, varscan2
- MED13L | c.1371A>G p.S457= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as COSV56129987; called by muse, mutect2, varscan2
- MFAP4 | c.177C>G p.P59= | Silent (SNP) | VAF 58/130 reads (45%) | catalogued as COSV55191843; called by muse, mutect2, varscan2
- MGAM | c.3519C>T p.Y1173= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs1266692848, COSV72075828; called by muse, mutect2, varscan2
- MGAT5B | c.1048C>A p.R350= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV56936626; called by muse, mutect2, varscan2
- MOV10L1 | c.2091C>T p.D697= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as COSV53178962; called by muse, mutect2, varscan2
- MUC20 | c.339A>T p.S113= | Silent (SNP) | VAF 48/320 reads (15%) | catalogued as COSV100291246; called by mutect2, varscan2
- MUC21 | c.1584A>C p.P528= | Silent (SNP) | VAF 40/240 reads (17%) | catalogued as COSV66222215; called by muse, mutect2, varscan2
- MYH13 | c.4950C>G p.V1650= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV52842398; called by muse, mutect2, varscan2
- MYH6 | c.2221A>C p.R741= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as COSV62454408; called by muse, mutect2, varscan2
- NANOG | c.639C>T p.I213= | Silent (SNP) | VAF 87/226 reads (38%) | catalogued as COSV99981605; called by muse, mutect2, varscan2
- NBEA | c.2517T>A p.I839= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV59822059; called by muse, mutect2, varscan2
- NBEAL2 | c.4548G>T p.L1516= | Silent (SNP) | VAF 35/40 reads (88%) | catalogued as COSV52762755; called by muse, mutect2, varscan2
- NES | c.2478A>T p.L826= | Silent (SNP) | VAF 120/185 reads (65%) | catalogued as COSV63962914; called by muse, mutect2, varscan2
- NIBAN2 | c.849C>A p.A283= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV64825543; called by muse, mutect2, varscan2
- NOBOX | c.1377T>C p.P459= | Silent (SNP) | VAF 66/136 reads (49%) | catalogued as COSV99779524; called by muse, mutect2, varscan2
- NOL6 | c.792G>C p.P264= | Silent (SNP) | VAF 44/93 reads (47%) | catalogued as COSV53045686; called by muse, mutect2, varscan2
- NOTCH3 | c.5064T>C p.S1688= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV54649401; called by muse, mutect2, varscan2
- NOVA2 | c.477G>A p.Q159= | Silent (SNP) | VAF 2/9 reads (22%) | catalogued as COSV54359847; called by muse, mutect2
- NPAP1 | c.702G>A p.L234= | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as COSV61511013; called by muse, mutect2, varscan2
- NPAS3 | c.1569G>C p.P523= (on ENST00000356141 / NM_001164749.2; = p.P491= on NM_022123.3) | Silent (SNP) | VAF 50/112 reads (45%) | catalogued as COSV60861683; called by muse, mutect2, varscan2
- NRCAM | c.2748G>A p.P916= (on ENST00000379028 / NM_001371124.1; = p.P900= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 58/99 reads (59%) | catalogued as rs1331489205, COSV61035887; called by muse, mutect2, varscan2
- OR14A16 | c.480C>A p.G160= | Silent (SNP) | VAF 51/223 reads (23%) | catalogued as COSV62927461; called by muse, mutect2, varscan2
- OR2A12 | c.717C>A p.T239= | Silent (SNP) | VAF 42/128 reads (33%) | catalogued as COSV68822009; called by muse, mutect2, varscan2
- OR2AG1 | c.615C>T p.T205= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as COSV56627562; called by muse, mutect2, varscan2
- OR2G6 | c.924T>C p.S308= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV58575850; called by muse, mutect2, varscan2
- OR4K17 | c.888A>C p.I296= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV59649137; called by muse, mutect2, varscan2
- OR51L1 | c.567A>G p.L189= | Silent (SNP) | VAF 51/118 reads (43%) | catalogued as COSV58625799; called by muse, varscan2
- OR8G2P | c.30T>A p.T10= | Silent (SNP) | VAF 53/124 reads (43%) | called by muse, mutect2, varscan2
- P3H2 | c.387G>A p.G129= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs867307031, COSV60027722; called by muse, mutect2
- PCDHAC1 | c.1935A>G p.P645= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs1554206364, COSV53868920; called by muse, mutect2, varscan2
- PCLO | c.9195A>T p.T3065= | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as COSV61665395; called by muse, mutect2, varscan2
- PEF1 | c.57A>T p.G19= | Silent (SNP) | VAF 97/249 reads (39%) | catalogued as COSV65484320; called by muse, mutect2, varscan2
- PHACTR3 | c.6C>G p.A2= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV63380464; called by muse, mutect2
- PLCB4 | c.597T>A p.I199= | Silent (SNP) | VAF 73/153 reads (48%) | catalogued as COSV53811135; called by muse, mutect2, varscan2
- PLCXD2 | c.90C>A p.V30= | Silent (SNP) | VAF 83/201 reads (41%) | catalogued as COSV67342199; called by muse, mutect2, varscan2
- PLXNA4 | c.2007A>G p.P669= | Silent (SNP) | VAF 46/79 reads (58%) | catalogued as rs1434809484, COSV58159631; called by muse, mutect2, varscan2
- POLH | c.417A>T p.A139= | Silent (SNP) | VAF 80/283 reads (28%) | catalogued as COSV64780984; called by muse, mutect2, varscan2
- POLQ | c.3630G>A p.Q1210= | Silent (SNP) | VAF 50/117 reads (43%) | catalogued as COSV51761145; called by muse, mutect2, varscan2
- PPP1R9A | c.858T>C p.S286= | Silent (SNP) | VAF 56/127 reads (44%) | catalogued as rs747634225, COSV56910294; called by muse, mutect2, varscan2
68 further variants in this file (0 protein-altering or splice-affecting, 53 silent, 15 other) are not listed here.
